Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QQ-01A (Primary Tumor).

[page 1 of 2]
Accession #: *[REDACTED]*

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Multinodular goiter FNA and papillary left thyroid nodule.

Specimens Submitted:

1: SP: Thyroid, total thyroidectomy

ICA-0-3

Carcinoma, Papillary (Thyroid) 8260/3

Site: Thyroid, NOS C73.9 LM 3/16/11

DIAGNOSIS:

1. SP: Thyroid, total thyroidectomy:

Tumor Type:

Three foci of papillary carcinoma: two classical type and one microcarcinoma

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Both lobes and isthmus

The largest tumor focus is located in the left lobe and isthmus. The smaller carcinoma is located in the right lobe. The microcarcinoma is noted in the left lobe.

Tumor Size:

Tumor in left lobe and isthmus: 3 cm, Tumor in right lobe, 1.2 cm. Microcarcinoma: 0.4 cm

Tumor Encapsulation:

The largest tumor focus is encapsulated with focal capsular invasion. The tumor focus in the right lobe is partially surrounded by capsule

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades the perithyroidal adipose tissue
Focal

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Gross foci present

[page 2 of 2]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis
Parathyroid Glands:
Not identified
Lymph Nodes:
One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "thyroidectomy" and consists of a markedly disrupted, unoriented thyroid weighing 16 g. The presumed right lobe measures 4.5 x 2.3 x 1.1 cm, the presumed left lobe measures 3.8 x 2.5 x 1.6 cm and the isthmus measures 2.2 x 1.8 x 0.7 cm. The external surface is covered by a thin fibrous capsule and scant skeletal muscle. There are several lymph nodes identified measuring up to 0.6 x 0.5 cm in greatest dimensions, which are entirely submitted. The specimen shows several previously incised areas. The first incised area is at a uniloculated cystic nodule involving the medial left lobe and left lateral isthmus. The nodule measures 3.0 x 2.2 x 2.0 cm. The inner surface shows a friable brown-tan papillary excrescence measuring 0.8 x 0.7 x 0.5 cm. An additional previously incised area on the right lobe reveals a 1.2 x 0.9 x 0.9 cm ill defined, firm, white-tan nodule which abuts the capsular surface. A sample of this area is given to TPS. The outer surface of the specimen is inked black. On cut section of the left lobe, there is an ill-defined, firm, white-tan nodule measuring 0.4 x 0.3 x 0.3 cm which abuts the capsular surface. Sections through the remaining tissue reveal red tan and beefy appearance. Specimen is entirely submitted.

Summary of sections:
LN - Lymph nodes
RL - right lobe
LL - left lobe
I - isthmus

Summary of Sections:

Part 1: SP: Thyroid, total thyroidectomy

Block	Sect. Site	PCs
4	I	4
7	LL	7
1	LN	1
6	RL	6

Source: NCI Genomic Data Commons file e8df9783-b8eb-4ddf-befa-ef33cfd035de (TCGA-DJ-A1QQ.692F9D3F-844B-45B5-9E10-4BEEC1FB93C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).